Surgical pathology report (de-identified scan), TCGA case TCGA-FE-A3PC, project TCGA-THCA (Thyroid Carcinoma), tissue source site Ohio State University, specimen TCGA-FE-A3PC-01A (Primary Tumor).

[page 1 of 3]
TI/PAI Discrepancy		☒

Print this Page

Specimen Description

Procurement date:

Surgical Pathology Report

*****Clinical History*****
Patient History: PAP CA of thyroid.

1CD-0-3
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

fw
2/5/12

*****Final Pathologic Diagnosis*****

- A. Soft tissue, central neck, excision:
- Lymph nodes (19/19) involved with microscopic subcapsular foci of metastatic papillary carcinoma.
Note: one of the sampled nodules corresponds to a small piece of mature thyroid parenchyma.
- B. Left superior parathyroid, excision:
- Minute fragment of lymphoid tissue with small psammoma bodies suspicious for metastatic papillary carcinoma.
- C. Thyroid, thyroidectomy:
- Papillary thyroid carcinoma, oncocytic type, left lobe (see synoptic report).
- Small follicular adenoma, right lobe (C1, tan-white firm nodule).
- Hyperplastic nodule with degenerative changes, right lobe (C2, nodule with hemorrhagic core).
- Hashimoto's thyroiditis.

*****Synoptic Report*****

SYNOPTIC REPORT FOR THYROID CANCER:
Specimen type: Total thyroidectomy.
Tumor location: Left lobe.
Tumor size: 5.2 x 3.5 x 2.0 cm
Histologic type: Papillary thyroid carcinoma.
Tumor grade: Well-differentiated.
Lymphatic/vascular invasion: No.

[page 2 of 3]
Capsular invasion: No.

Tumor extent:

Confined to the thyroid: Yes.

Multifocal: No.

Invasion of thyroid cartilage or hyoid bone: No.

Infiltration of adjacent structures: No.

Lymph nodes:

Total number examined: 19

Sites/laterality: Central neck.

Number positive: 19

Number negative: 0

Extranodal extension: No.

Additional pathologic findings: Hashimoto's thyroiditis and small follicular adenoma.

pTNM: pT3N1Mx.

The above synoptic report complies, in slightly modified form, with the guidelines of the ^f for the reporting of cancer specimens

*****INTRAOPERATIVE CONSULTATION DIAGNOSIS:*****

AF1. Central neck dissection: (FROZEN SECTION PERFORMED)

- Five lymph nodes examined out of 20, those five are benign.

Note: [REDACTED] was here and requested RS4 for part A.

BF1. Left superior parathyroid: (FROZEN SECTION PERFORMED)

- Benign.

*****SPECIMEN(S) RECEIVED:*****

A: Neck (not radical neck),

B: Parathyroid,

C: Thyroid,

*****GROSS DESCRIPTION:*****

The specimens are received in three properly labeled containers, two of which are submitted for frozen section, with the patient's name and accession number.

A. The specimen is designated "central neck dissection" and consists of a 3.0 x 2.5 x 1.0 cm portion of tan-pink to yellow soft tissue. Upon dissection 20 lymph nodes are identified that range in size from 0.3 x 0.3 x 0.2 cm to 1.2 x 0.6 x 0.4 cm. All that remains in the container is adipose tissue. AF1 is resubmitted as received.

Summary of Cassettes: AF1, frozen section; A1, six possible lymph nodes; A2, six possible lymph nodes; A3, three possible lymph nodes

B. The specimen is designated "left superior parathyroid" and

[page 3 of 3]
consists of a 0.2 x 0.2 x 0.1 cm aggregate of soft tan-pink tissue which weighs less than 0.5 grams. BFl is resubmitted as received.

C. The specimen is designated "total thyroidectomy" and consists of a 41.9 gram total thyroid that measures 9.0 x 5.5 x 2.5 cm. The external surface is tan-pink to purple and slightly shaggy. The right lobe is inked in blue, the left lobe is inked in black, and the isthmus is inked green. On cut section, the right lobe contains one tan-white nodule which measures 1.1 x 1.0 x 1.0 cm and has a central area of hemorrhage and necrosis. This nodule comes to within 3.0 cm from the isthmus. The right lobe contains a second tan-white and firm nodule which measures 0.9 x 0.7 x 0.8 cm, and is 1.8 cm from the isthmus. Both of the nodules in the right lobe grossly appear to abut the capsule. On cut section, the left lobe contains a tan-white and indurated rim of tissue surrounding a tan-pink and finely granular and friable area, which measures 5.2 x 3.5 x 2.0 cm and abuts the capsule. The left lobe is serially sectioned with the lateral edge of the left lobe transected with perpendicular sections of it. The entire left lobe with the nodule is submitted. The remaining parenchyma is beefy red and unremarkable. (P)

Summary of Cassettes: C1, representative section of tan-white and firm nodule from right lobe; C2, representative section of nodule with hemorrhagic core from right lobe; C3-18, with C4-15 entire left lobe; C16-18, lateral portion of left thyroid transected and perpendicularly sectioned; C19, uninvolved right lobe, C20, uninvolved isthmus; C21, uninvolved left lobe

Source: NCI Genomic Data Commons file c445c9d8-ba89-498d-939b-a4b024bdfbfa (TCGA-FE-A3PC.5811676B-2274-40D5-9CBA-36468ACAF6B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).